Surgical pathology report (de-identified scan), TCGA case TCGA-49-4487, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Johns Hopkins, specimen TCGA-49-4487-01A (Primary Tumor).

1. FINAL DIAGNOSIS ----- Pathologist: [REDACTED]

1. LUNG (LOBECTOMY): MODERATELY DIFFERENTIATED ADENOCARCINOMA. THE SURGICAL MARGINS ARE FREE OF TUMOR. THERE IS FOCAL VASCULAR INVASION WITHIN THE TUMOR. THE BRONCHIAL MARGIN IS NEGATIVE. THREE (3) BRONCHOPULMONARY NODES FROM THE SPECIMEN (LEVEL 11L?) ARE NEGATIVE.
2. RIB (LOBECTOMY): NEGATIVE FOR TUMOR, GROSS DIAGNOSIS ONLY.
3. INNOMINATE LYMPH NODE (BX.): ONE (1) LYMPH NODE AND ASSOCIATED SOFT TISSUE, NEGATIVE FOR TUMOR.
- [REDACTED]
- [REDACTED]
- [REDACTED]

Source: NCI Genomic Data Commons file 4e588cf6-783d-4ec1-ba10-b305b62848f8 (TCGA-49-4487.C67031FC-F601-4BD2-B8FD-429A0664CC65.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).